Somatic mutation profile of tumor specimen TCGA-56-8629-01A (aliquot TCGA-56-8629-01A-11D-2395-08) from TCGA case TCGA-56-8629, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.9 years (23,346 days).
Specimen TCGA-56-8629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f09a4d66-f922-42e0-aa98-51142aa73426.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8629-10A (Blood Derived Normal), aliquot TCGA-56-8629-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f0dccb6-ced7-4f42-9428-00584ac9e884

The open-access MAF lists 244 somatic variants for this specimen: 185 protein-altering or splice-affecting, 53 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 53, Nonsense Mutation 18, Frame Shift Del 9, Splice Site 7, Frame Shift Ins 4, RNA 3, Intron 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC8 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 29/98 reads (30%) | catalogued as CM072819, CM131651, COSV100217551, COSV56852798; called by muse, mutect2, varscan2
- ACADM | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs376982913; called by muse, mutect2
- ACAP2 | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100462518; called by muse, mutect2, varscan2
- ACTC1 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as COSV99292047; called by muse, mutect2, varscan2
- ADA | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV100596145; called by muse, mutect2, varscan2
- ADAM32 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.664); catalogued as COSV101165447; called by muse, mutect2, varscan2
- ADAMTS12 | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as COSV100711433, COSV61260149, COSV61262502; called by muse, mutect2, varscan2
- AKIRIN2 | c.436C>G p.R146G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100005268; called by muse, mutect2, varscan2
- AOAH | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99333349; called by muse, mutect2, varscan2
- ARHGAP15 | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as COSV54494546, COSV54497758; called by muse, mutect2, varscan2
- ARHGAP31 | c.3168G>C p.Q1056H | Missense Mutation (SNP) | VAF 267/445 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.365); catalogued as COSV99957436; called by muse, mutect2, varscan2
- ARHGEF10L | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1469588059, COSV51436810; called by muse, mutect2, varscan2
- ARHGEF4 | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as COSV100388450; called by muse, mutect2, varscan2
- ARMH4 | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99958656; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1386C>A p.Y462* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as COSV52269233, COSV99314312, COSV99314384; called by muse, mutect2, varscan2
- ATXN1 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 120/167 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1428336701, COSV99787120; called by muse, mutect2, varscan2
- BCHE | c.782T>A p.V261E | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV100012843; called by muse, mutect2
- BIRC6 | c.10989A>C p.K3663N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV101428512; called by muse, mutect2, varscan2
- BMP4 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV99817058; called by muse, mutect2, varscan2
- C2orf69 | c.831G>C p.L277F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1313265781, COSV100178926; called by muse, mutect2, varscan2
- C9orf153 | c.19A>C p.T7P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV100188717; called by muse, mutect2, varscan2
- CABIN1 | c.4379C>T p.T1460I | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99573715; called by muse, mutect2, varscan2
- CACNA1A | c.2050G>T p.V684L | Missense Mutation (SNP) | VAF 110/193 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100802949, COSV64213082; called by muse, mutect2, varscan2
- CCZ1B | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV100367706, COSV57438014; called by muse, mutect2, varscan2
- CDH10 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52589393; called by muse, mutect2, varscan2
- CDH6 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 70/124 reads (56%) | catalogued as COSV54077333, COSV99420123; called by muse, mutect2, varscan2
- CDHR1 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.257); catalogued as rs771658854, COSV100258346, COSV100259224; called by muse, mutect2, varscan2
- CEP152 | c.3987A>T p.E1329D (on ENST00000380950 / NM_001194998.2; = p.E1273D on NM_014985.4) | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100359019; called by muse, mutect2, varscan2
- CFHR3 | c.36G>C p.W12C | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100807684; called by muse, mutect2, varscan2
- CHD6 | c.6532A>T p.R2178W | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100950604, COSV100951250; called by muse, mutect2, varscan2
- CHEK1 | c.1211G>A p.W404* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99629797; called by muse, varscan2
- CHMP3 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as COSV99806774; called by muse, mutect2
- CHRNA1 | c.714C>A p.C238* (on ENST00000261007 / NM_001039523.3; = p.C213* on NM_000079.4) | Nonsense Mutation (SNP) | VAF 55/205 reads (27%) | catalogued as COSV99650587; called by muse, mutect2, varscan2
- COL11A1 | c.72G>C p.L24F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100617641; called by muse, mutect2, varscan2
- COLGALT2 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100730790; called by muse, mutect2, varscan2
- CORIN | c.1590-1G>T p.X530_splice | Splice Site (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99904104; called by muse, mutect2, varscan2
- CSDE1 | c.1854G>T p.M618I (on ENST00000358528 / NM_001007553.3; = p.M587I on NM_007158.6) | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99795569; called by muse, mutect2, varscan2
- CXCL14 | c.230G>T p.R77M (on ENST00000337225; = p.R65M on NM_004887.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100463586, COSV61499492; called by muse, mutect2, varscan2
- CYP4F22 | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99512985; called by muse, mutect2, varscan2
- CYSLTR1 | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100964747; called by muse, mutect2, varscan2
- DNAH5 | c.9941del p.R3314Pfs*24 | Frame Shift Del (DEL) | VAF 60/348 reads (17%) | catalogued as COSV99445373; called by mutect2, pindel, varscan2
- EML5 | c.4998C>G p.I1666M (on ENST00000380664; = p.I1674M on NM_183387.3) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100715996; called by muse, mutect2, varscan2
- EPG5 | c.1411G>C p.G471R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99957747; called by muse, mutect2, varscan2
- ERBB4 | c.806A>T p.N269I | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99628981; called by muse, mutect2, varscan2
- EWSR1 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100131903; called by muse, mutect2
- F13A1 | c.1770C>G p.I590M | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.671); catalogued as COSV99341873; called by muse, mutect2, varscan2
- FAM160A2 | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.594); catalogued as COSV99792309; called by muse, mutect2, varscan2
- FAM83C | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as COSV100981626, COSV65584450; called by muse, mutect2, varscan2
- FAR2 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV99479434; called by muse, mutect2, varscan2
- FBXL7 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs766043354, COSV100310366, COSV61650035; called by muse, mutect2, varscan2
- FBXW10 | c.2699A>C p.H900P | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100111607; called by muse, mutect2, varscan2
- FCRL5 | c.749T>G p.M250R | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100709153; called by muse, mutect2, varscan2
- FIZ1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.176); catalogued as rs767369020, COSV55607227, COSV55609246; called by muse, mutect2
- GBA | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as COSV100516422; called by mutect2, varscan2
- GCN1 | c.5264G>C p.G1755A | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100325709; called by muse, mutect2, varscan2
- GOLGA3 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV99212259; called by muse, mutect2
- GPA33 | c.468C>G p.N156K | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV100901170; called by muse, mutect2, varscan2
- GPR149 | c.1140G>C p.Q380H | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV101078608; called by muse, mutect2, varscan2
- GPR32 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99567311; called by muse, mutect2, varscan2
- GPR39 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV100258157; called by muse, mutect2, varscan2
- GPR39 | c.825G>T p.R275S | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.438); catalogued as COSV100258159; called by muse, mutect2, varscan2
- GSE1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs750219239, COSV53671474; called by muse, mutect2, varscan2
- H4C4 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV100534460; called by muse, mutect2, varscan2
- IHH | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1316070321, COSV99838742; called by muse, mutect2, varscan2
- IPO8 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99805529; called by muse, mutect2, varscan2
- ISM1 | c.780C>A p.N260K | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.089); catalogued as rs1255959018, COSV99340145; called by muse, mutect2, varscan2
- KRT75 | c.662T>A p.L221H | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99359522; called by muse, mutect2, varscan2
- LBHD1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100649200; called by muse, mutect2, varscan2
- LHCGR | c.1319G>T p.S440I | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV99684011; called by muse, mutect2, varscan2
- LPAR2 | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV101345510; called by muse, mutect2, varscan2
- LPIN2 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as rs375162582; called by muse, mutect2, varscan2
- LRP5 | c.4097A>T p.D1366V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99592402; called by muse, mutect2, varscan2
- LRRIQ3 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as rs771944726, COSV63042957, COSV63045333; called by muse, mutect2, varscan2
- LTN1 | c.934G>C p.V312L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100798091; called by muse, mutect2, varscan2
- MAP9 | c.40A>T p.K14* | Nonsense Mutation (SNP) | VAF 25/38 reads (66%) | catalogued as COSV100251029; called by muse, mutect2, varscan2
- MED13 | c.4901C>T p.T1634M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs779887785, COSV101181205, COSV67267088; called by muse, mutect2, varscan2
- METTL2A | c.883del p.R295Afs*21 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as COSV100274283; called by mutect2, pindel, varscan2
- MKRN3 | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); catalogued as rs751110028, COSV100091426; called by muse, mutect2, varscan2
- MUC20 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100291394; called by muse, mutect2, varscan2
- MYH3 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 117/180 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs148637119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- N6AMT1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV100375054; called by mutect2, varscan2
- NCOA3 | c.2330C>G p.S777* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100507922; called by muse, mutect2, varscan2
- NCOR1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51963704, COSV99251193; called by muse, mutect2, varscan2
- NEBL | c.1179G>C p.K393N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.231); catalogued as COSV101009293; called by muse, mutect2, varscan2
- NEU4 | c.313del p.V105Cfs*218 (on ENST00000391969 / NM_001167602.3; = p.V117Cfs*218 on NM_080741.4) | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as COSV57989779; called by mutect2, pindel, varscan2
- NUP35 | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV99717901; called by muse, mutect2, varscan2
- OR14C36 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as COSV58601166; called by muse, mutect2, varscan2
- OR4B1 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1240505597, COSV100535659; called by muse, mutect2, varscan2
- OR4M1 | c.18C>A p.Y6* | Nonsense Mutation (SNP) | VAF 45/151 reads (30%) | catalogued as COSV100271367; called by muse, mutect2, varscan2
- OR5M10 | c.588del p.M197Wfs*5 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as COSV73242260, COSV73242270; called by mutect2, varscan2
- PAFAH2 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100959348; called by muse, mutect2, varscan2
- PAPPA2 | c.3777A>C p.K1259N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs775159487, COSV100868382, COSV62792536; called by muse, mutect2, varscan2
- PAX3 | c.915C>A p.Y305* | Nonsense Mutation (SNP) | VAF 158/247 reads (64%) | catalogued as COSV100399920; called by muse, mutect2, varscan2
- PCDHGA3 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV99542946; called by muse, mutect2, varscan2
- PDE1A | c.1469A>G p.Y490C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100115479; called by muse, mutect2, varscan2
- PDGFD | c.434A>T p.N145I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100160154; called by muse, mutect2, varscan2
- PIEZO2 | c.6949C>T p.R2317* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as rs1329879893, COSV53290118, COSV99555074; called by muse, mutect2, varscan2
- PIK3CG | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs796052174, CM156432, COSV100783037, COSV63247729; called by muse, mutect2, varscan2
- PKHD1 | c.9544G>T p.V3182L | Missense Mutation (SNP) | VAF 115/148 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100583949; called by muse, mutect2, varscan2
- PKP4 | c.3260C>G p.S1087C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100733921; called by muse, mutect2, varscan2
- PLCL1 | c.1481A>T p.H494L | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101407218; called by muse, mutect2, varscan2
- PLD1 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 8/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60570184; called by muse, mutect2
- PLEKHG4B | c.2789C>T p.A930V (on ENST00000283426; = p.A1286V on NM_052909.5) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99360775; called by muse, mutect2, varscan2
- POU4F2 | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV99850702; called by muse, mutect2, varscan2
- PPM1B | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV99175849; called by muse, mutect2, varscan2
- PPP1R26 | c.2675G>T p.S892I | Missense Mutation (SNP) | VAF 82/137 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100778118; called by muse, mutect2, varscan2
- PRRC2C | c.265A>G p.K89E (on ENST00000367742; = p.K87E on NM_015172.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100145624; called by muse, mutect2, varscan2
- PRSS58 | c.577-1G>T p.X193_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | catalogued as COSV101616153; called by muse, mutect2, varscan2
- PSG1 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740879; called by muse, varscan2
- PTPN21 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.426); catalogued as COSV100162305; called by muse, mutect2, varscan2
- RABGAP1L | c.1489G>C p.G497R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99272535; called by muse, mutect2, varscan2
- RABGAP1L | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99272544; called by muse, mutect2, varscan2
- RADIL | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101271549; called by muse, mutect2, varscan2
- RANBP17 | c.2118C>A p.N706K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV101206347; called by muse, mutect2, varscan2
- REG1A | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1336171875, COSV52068864; called by muse, mutect2, varscan2
- RFC5 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99969963; called by muse, mutect2, varscan2
- RPL31 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs1327332992, COSV99961545; called by muse, mutect2, varscan2
- RSBN1 | c.928A>T p.R310W | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99793475; called by muse, mutect2, varscan2
- RTF1 | c.2018C>G p.P673R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101048058; called by muse, mutect2, varscan2
- RYR3 | c.7308C>A p.H2436Q (on ENST00000389232; = p.H2437Q on NM_001036.6) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV101213386; called by muse, mutect2, varscan2
- SAGE1 | c.1082A>C p.N361T | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV100187653; called by muse, mutect2, varscan2
- SCN10A | c.3823G>T p.V1275L | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as COSV101479479; called by muse, mutect2, varscan2
- SERPINA5 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.254); catalogued as COSV100291738; called by muse, mutect2, varscan2
- SETD2 | c.5266G>T p.E1756* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV57447230, COSV57455108; called by muse, mutect2, varscan2
- SH3RF1 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99498687, COSV99499297; called by muse, mutect2, varscan2
- SIPA1L1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139982852; called by muse, mutect2
- SLC29A3 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 173/248 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs769137288, COSV100928558; called by muse, mutect2, varscan2
- SLC2A2 | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100049447; called by muse, mutect2, varscan2
- SLC5A6 | c.1095-2A>T p.X365_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100143441; called by muse, mutect2, varscan2
- SLC5A7 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV99887058; called by muse, mutect2, varscan2
- SLC6A13 | c.500A>T p.K167M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100570014; called by muse, mutect2, varscan2
- SLC6A17 | c.1737C>A p.C579* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as COSV100521438; called by muse, mutect2, varscan2
- SLC8A2 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99370205; called by muse, mutect2, varscan2
- SLC9A2 | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV52135245, COSV99296549; called by muse, mutect2, varscan2
- SLCO6A1 | c.762T>G p.I254M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV101134718; called by muse, mutect2, varscan2
- SLITRK1 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV101000018; called by muse, mutect2, varscan2
- SNTB2 | c.1433G>T p.S478I | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV100293292; called by muse, mutect2, varscan2
- SPG7 | c.435G>T p.L145F | Missense Mutation (SNP) | VAF 88/117 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.204); catalogued as COSV99245195; called by muse, mutect2, varscan2
- SPX | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV57021439; called by muse, mutect2, varscan2
- SSH1 | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100425730; called by muse, mutect2, varscan2
- STK36 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs748161203, COSV99830932; called by muse, mutect2, varscan2
- SYDE2 | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99320565; called by muse, mutect2, varscan2
- TAAR6 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 77/105 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99256825; called by muse, mutect2, varscan2
- TECTA | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99880805; called by muse, mutect2, varscan2
- TENM1 | c.6830C>G p.P2277R | Missense Mutation (SNP) | VAF 92/118 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100950480; called by muse, mutect2, varscan2
- TENM3 | c.6814T>A p.S2272T | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1324958468, COSV101305301; called by muse, mutect2, varscan2
- TIMD4 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV50854054; called by muse, mutect2, varscan2
- TMEM25 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100244850; called by muse, mutect2, varscan2
- TMTC1 | c.1716G>C p.K572N (on ENST00000539277 / NM_001193451.2; = p.K464N on NM_175861.3) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV99760414; called by muse, mutect2, varscan2
- TOP1 | c.156-1G>T p.X52_splice | Splice Site (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100793914, COSV63694924; called by muse, mutect2, varscan2
- TRIM5 | c.709C>G p.H237D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100000509; called by muse, mutect2, varscan2
- TRPM3 | c.948A>T p.E316D (on ENST00000357533 / NM_001366142.2; = p.E161D on NM_020952.6) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100625271; called by muse, mutect2, varscan2
- TSHZ2 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100296505; called by muse, mutect2, varscan2
- TTLL5 | c.2833C>G p.P945A | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100091092; called by muse, mutect2, varscan2
- TTN | c.50320G>A p.D16774N (on ENST00000591111; = p.D9350N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | PolyPhen possibly damaging (0.642); catalogued as COSV100622530; called by muse, mutect2, varscan2
- TTN | c.3407C>A p.T1136N (on ENST00000591111; = p.T1090N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | PolyPhen possibly damaging (0.676); catalogued as COSV100622538; called by muse, mutect2, varscan2
- UBIAD1 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100954923, COSV65147658; called by muse, mutect2, varscan2
- UBR4 | c.3741+1G>T p.X1247_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100921381; called by muse, mutect2, varscan2
- UGT2B28 | c.1000A>C p.K334Q | Missense Mutation (SNP) | VAF 76/121 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100158946; called by muse, mutect2, varscan2
- USP30 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99980500; called by muse, mutect2, varscan2
- USP36 | c.2860A>T p.R954W | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100361689; called by muse, mutect2, varscan2
- WWC2 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs574309917, COSV100968470; called by muse, mutect2, varscan2
- XYLT1 | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as COSV99762736; called by muse, mutect2, varscan2
- ZDHHC3 | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV99943579; called by muse, mutect2, varscan2
- ZNF280A | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100131154; called by muse, mutect2, varscan2
- ZNF429 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100642004, COSV61915610; called by muse, mutect2, varscan2
- ZNF526 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100004553; called by muse, mutect2, varscan2
- ZNF536 | c.1260G>T p.Q420H | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV100835549; called by muse, mutect2, varscan2
- ZNF571 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV100143912; called by muse, mutect2
- BAK1 | c.351-3_351-2del p.X117_splice | Splice Site (DEL) | VAF 50/96 reads (52%) | called by pindel, varscan2
- BRINP3 | c.1694dup p.L565Ffs*18 | Frame Shift Ins (INS) | VAF 58/144 reads (40%) | called by mutect2, pindel, varscan2
- C1orf162 | c.202+3_202+11del p.X68_splice | Splice Site (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- CYBB | c.1425C>A p.S475R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- DIP2B | c.2315dup p.N772Kfs*4 | Frame Shift Ins (INS) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- DST | c.14028del p.T4677Lfs*9 (on ENST00000361203 / NM_001374722.1; = p.T2265Lfs*9 on NM_015548.5) | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | called by mutect2, pindel, varscan2
- HSPA8 | c.1748dup p.N584Efs*5 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel
- IGKV6D-41 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KIAA1109 | c.5759del p.G1920Vfs*12 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | called by mutect2, pindel, varscan2
- MFSD1 | c.1088dup p.L364Tfs*20 | Frame Shift Ins (INS) | VAF 30/284 reads (11%) | called by mutect2, pindel, varscan2
- MON1B | c.1050_1061delinsT p.L351Hfs*4 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | called by pindel, varscan2*
- MYO10 | c.1429del p.E477Kfs*3 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | called by mutect2, pindel, varscan2
- OBSCN | c.12160del p.H4054Tfs*31 | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.240T>G p.D80E | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF461 | c.552_560del p.E184_Y186del | In Frame Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- ABCA13 | c.870C>A p.I290= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV101330127; called by muse, mutect2, varscan2
- ACVR1 | c.1113G>A p.G371= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV99717959; called by muse, mutect2, varscan2
- ADGRL4 | c.648T>C p.N216= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100876322; called by muse, mutect2, varscan2
- ANO8 | c.2046C>A p.A682= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV99344721; called by muse, varscan2
- APOB | c.11835T>A p.T3945= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV99266857; called by muse, mutect2, varscan2
- ARMH4 | c.1284C>T p.N428= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs183669375, COSV99957497; called by muse, mutect2, varscan2
- ATRN | c.3498C>G p.T1166= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV99497579; called by muse, mutect2, varscan2
- AVPR2 | c.252C>A p.A84= | Silent (SNP) | VAF 47/69 reads (68%) | catalogued as COSV100509610; called by muse, mutect2, varscan2
- CEMIP | c.2361C>T p.Y787= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99587041; called by muse, mutect2, varscan2
- CHST1 | c.588G>A p.A196= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV57325828; called by muse, mutect2, varscan2
- DDX47 | c.1095T>A p.T365= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100774609; called by muse, mutect2, varscan2
- EXTL1 | c.837T>C p.R279= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as COSV100959118; called by muse, mutect2, varscan2
- FASTKD1 | c.651A>G p.E217= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101328524; called by muse, mutect2, varscan2
- FGD3 | c.672G>T p.T224= | Silent (SNP) | VAF 72/119 reads (61%) | catalogued as COSV100490741; called by muse, mutect2, varscan2
- FNDC3B | c.1026G>C p.L342= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as COSV100394594; called by muse, mutect2, varscan2
- FUT2 | c.861C>G p.T287= | Silent (SNP) | VAF 61/327 reads (19%) | catalogued as COSV101218129; called by muse, mutect2, varscan2
- GIGYF1 | c.1542C>T p.C514= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as rs770517974, COSV99309736; called by muse, mutect2, varscan2
- GP6 | c.885G>A p.R295= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100117677; called by muse, mutect2
- IFT57 | c.642G>A p.Q214= | Silent (SNP) | VAF 30/48 reads (63%) | catalogued as COSV99197910; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.333T>C p.A111= | Silent (SNP) | VAF 174/397 reads (44%) | called by muse, mutect2, varscan2
- MCOLN1 | c.231G>T p.T77= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as COSV51180676, COSV99900743; called by muse, mutect2, varscan2
- MFAP5 | c.510C>T p.P170= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100848173; called by muse, mutect2, varscan2
- NME7 | c.492A>G p.L164= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs765501705, COSV100891117; called by muse, mutect2, varscan2
- OR10K2 | c.123C>A p.T41= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as COSV100149588; called by muse, mutect2, varscan2
- OR10W1 | c.624C>G p.S208= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV101223754; called by muse, mutect2, varscan2
- OR2L2 | c.321A>C p.A107= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as COSV100824187; called by muse, mutect2, varscan2
- OR4C16 | c.744C>T p.F248= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1482959804, COSV100113734, COSV58944289; called by muse, mutect2, varscan2
- PCDHB10 | c.768C>A p.P256= | Silent (SNP) | VAF 44/65 reads (68%) | catalogued as rs1183575523, COSV53378286, COSV99504739; called by muse, mutect2, varscan2
- PCDHB5 | c.2040C>A p.A680= | Silent (SNP) | VAF 154/276 reads (56%) | catalogued as COSV99169296; called by muse, varscan2
- PKD1 | c.9519G>T p.P3173= | Silent (SNP) | VAF 57/135 reads (42%) | catalogued as COSV99238650; called by muse, mutect2, varscan2
- PLCH1 | c.2394A>T p.T798= (on ENST00000340059 / NM_001130960.2; = p.T810= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100397699; called by muse, mutect2, varscan2
- PLEC | c.13539G>A p.K4513= (on ENST00000322810 / NM_201380.4; = p.K4403= on NM_000445.5) | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs1433237673, COSV100516830; called by muse, mutect2, varscan2
- PNMA8A | c.882C>T p.P294= | Silent (SNP) | VAF 115/295 reads (39%) | catalogued as rs368577488; called by muse, mutect2, varscan2
- POLR3C | c.1401A>T p.V467= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV100493016; called by muse, mutect2, varscan2
- RPTOR | c.3474G>A p.V1158= | Silent (SNP) | VAF 80/168 reads (48%) | catalogued as COSV100156821; called by muse, mutect2, varscan2
- S100A7 | c.96G>A p.L32= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as COSV100906753; called by muse, mutect2, varscan2
- SCML4 | c.204G>A p.R68= | Silent (SNP) | VAF 109/148 reads (74%) | catalogued as COSV100940400; called by muse, mutect2, varscan2
- SEMA3F | c.735G>T p.T245= | Silent (SNP) | VAF 86/122 reads (70%) | catalogued as COSV50033027, COSV99137709; called by muse, mutect2, varscan2
- SEMA5B | c.3438G>C p.R1146= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99532667; called by muse, mutect2, varscan2
- SETDB1 | c.3186T>C p.G1062= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV99645432; called by muse, mutect2, varscan2
- SH3GL3 | c.894A>T p.P298= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100197173; called by muse, mutect2, varscan2
- SLC26A4 | c.933T>G p.T311= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99707301; called by muse, mutect2, varscan2
- SOST | c.198C>A p.P66= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV100059739; called by muse, mutect2, varscan2
- SYNE1 | c.6366A>G p.K2122= (on ENST00000367255 / NM_182961.4; = p.K2129= on NM_033071.3) | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV99573104; called by muse, mutect2, varscan2
- TAS2R41 | c.867G>A p.K289= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs1265029054, COSV101281506; called by muse, mutect2, varscan2
- TBC1D22A | c.1486C>T p.L496= | Silent (SNP) | VAF 179/333 reads (54%) | catalogued as rs1422891692, COSV100453484; called by muse, mutect2, varscan2
- TBX22 | c.438G>C p.P146= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV100960888, COSV100960938; called by muse, mutect2, varscan2
- TTC23L | c.492C>T p.V164= | Silent (SNP) | VAF 34/223 reads (15%) | catalogued as COSV101551147; called by muse, mutect2, varscan2
- TTN | c.3408C>A p.T1136= (on ENST00000591111; = p.T1090= on NM_003319.4) | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs759010767, COSV100622533, COSV60324372; called by muse, mutect2, varscan2
- WIF1 | c.649C>A p.R217= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54131155, COSV99683195; called by muse, mutect2, varscan2
- ZNF530 | c.1563C>T p.C521= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs551484617, COSV60532338; called by muse, mutect2, varscan2
- ZNRF3 | c.2238G>T p.A746= (on ENST00000544604 / NM_001206998.2; = p.A646= on NM_032173.3) | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV100238261, COSV60438619; called by muse, mutect2, varscan2
- ZPBP | c.513T>C p.Y171= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99250171; called by muse, mutect2, varscan2
- CARMIL1 | c.614+1535G>C | Intron (SNP) | VAF 45/62 reads (73%) | called by muse, mutect2, varscan2
- DMD | c.*31G>T | 3'UTR (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100628496; called by muse, mutect2, varscan2
- OR2W5 | n.429G>T | RNA (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- SETX | c.7287+180C>G | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99810421; called by muse, mutect2, varscan2
- SSPOP | n.15548G>T | RNA (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100947772; called by muse, mutect2, varscan2
- UBTFL2 | n.26G>T | RNA (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
